Somatic mutation profile of tumor specimen TCGA-W2-A7H7-01A (aliquot TCGA-W2-A7H7-01A-11D-A35I-08) from TCGA case TCGA-W2-A7H7, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 59.4 years (21,711 days).
Specimen TCGA-W2-A7H7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91d2d1af-7e6a-4780-a81d-797ae6f5b0e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W2-A7H7-10A (Blood Derived Normal), aliquot TCGA-W2-A7H7-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d472a07-6820-40f8-be48-911970a593df

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 5, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1G3 | c.146T>C p.M49T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.598); catalogued as COSV99810696; called by muse, mutect2, varscan2
- GON4L | c.5785G>T p.E1929* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV55188347; called by muse, mutect2, varscan2
- OR10R2 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63768728; called by muse, mutect2
- CENPB | c.1678T>A p.S560T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- JADE1 | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- KDM4B | c.2719A>G p.K907E | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ALDH7A1 | c.840A>G p.K280= | Silent (SNP) | VAF 35/113 reads (31%) | called by muse, mutect2, varscan2
- COL6A6 | c.432G>A p.E144= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs1347677287; called by muse, mutect2, varscan2
- GPC5 | c.895T>C p.L299= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs759363776; called by muse, mutect2, varscan2
- LPL | c.609A>G p.A203= | Silent (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- NOA1 | c.1674C>T p.V558= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs763237184, COSV51738167; called by muse, mutect2, varscan2
